RC case RC-B65L — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b84904d6-c587-4358-b948-f7bb55c8bfb8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1956; Vital status: Alive.

Diagnoses (2)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 64.0 years (23,375 days); Year of diagnosis: 2020; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann arbor b symptoms described array: Fever / Night Sweats; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Inguinal / Lymph Node, Para-Aortic.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 3 cm; Timepoint category: Initial Diagnosis.
   Recorded as not given: Organ Transplantation; adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, NOS.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 63.2 years (23,096 days); Year of diagnosis: 2019; Days to diagnosis: -279 days; AJCC staging edition: 8th; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -279 days; Treatment anatomic sites: Kidney.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Days to follow up: 136 days; Disease response: Tumor Free.
- Day 459 (end of treatment course 1): Disease response: Tumor Free.
- Days to follow up: 883 days (2.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Lactate Dehydrogenase 290 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (IHC): Negative.
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension / Sleep Apnea / Benign Prostatic Hyperplasia.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash / Hepatitis B Infection / Epstein-Barr Virus.
- Timepoint category: Initial Diagnosis; Weight: 91.4 kg; Height: 176 cm; BMI: 29.5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B65L-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65L-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B65L-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 7; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
